Somatic mutation profile of cancer-model specimen HCM-CSHL-0510-D13-85A (3D Organoid, passage 5; aliquot HCM-CSHL-0510-D13-85A-01D-A82H-36), derived from the primary tumor of HCMI case HCM-CSHL-0510-D13, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 59.1 years (21,570 days).
Specimen HCM-CSHL-0510-D13-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9567a8d-be4c-46c1-892d-3e21da4078f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0510-D13-10A (Blood Derived Normal), aliquot HCM-CSHL-0510-D13-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e6ea8e8-f61c-4701-ac97-743b8de54cf4

The open-access MAF lists 186 somatic variants for this specimen: 139 protein-altering or splice-affecting, 43 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 43, Frame Shift Ins 4, Nonsense Mutation 3, Frame Shift Del 2, 3'Flank 1, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 194/426 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 114/340 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 36/694 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2
- SMARCA4 | c.3694G>A p.G1232S | Missense Mutation (SNP) | VAF 28/724 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV60785813, COSV60799159; called by muse, mutect2
- ADAMTS10 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 25/596 reads (4%) | SIFT tolerated (0.99); PolyPhen benign (0.033); catalogued as rs539576977, COSV99547611; called by muse, mutect2
- ADGRA1 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 334/705 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs779122897, COSV66926538; called by muse, mutect2, varscan2
- ALG12 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 26/658 reads (4%) | PolyPhen benign (0); catalogued as rs778608834; called by muse, mutect2
- APC | c.4178T>A p.L1393H | Missense Mutation (SNP) | VAF 113/234 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57402309; called by muse, mutect2, varscan2
- APC | c.4391_4394del p.E1464Vfs*8 | Frame Shift Del (DEL) | VAF 221/233 reads (95%) | catalogued as rs387906234; called by mutect2, pindel, varscan2
- ARHGAP17 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.063); catalogued as rs746155178; called by muse, mutect2, varscan2
- ASB2 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 143/625 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs773111415; called by muse, mutect2, varscan2
- AXL | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 242/547 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs138219571; called by muse, mutect2, varscan2
- BRINP1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 206/456 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs987725274, COSV56293277; called by muse, mutect2, varscan2
- BRWD3 | c.2888C>A p.S963* | Nonsense Mutation (SNP) | VAF 39/100 reads (39%) | catalogued as COSV64751280; called by muse, mutect2, varscan2
- C10orf71 | c.121T>G p.C41G | Missense Mutation (SNP) | VAF 20/541 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60514516; called by muse, mutect2
- CACNA1A | c.2840G>A p.R947H | Missense Mutation (SNP) | VAF 273/810 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); catalogued as rs753862352; called by muse, varscan2
- CAMTA1 | c.1991C>T p.T664M | Missense Mutation (SNP) | VAF 367/664 reads (55%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.105); catalogued as rs576226270, COSV57903148, COSV57916355; called by muse, mutect2, varscan2
- CATSPER4 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 216/467 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs781301429; called by muse, mutect2, varscan2
- CCDC168 | c.13968G>T p.E4656D | Missense Mutation (SNP) | VAF 18/419 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.801); catalogued as rs930520789, COSV100487810; called by muse, mutect2
- CD2AP | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 147/306 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as rs779860972; called by muse, mutect2, varscan2
- CDH12 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 222/471 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs147080212; called by muse, mutect2, varscan2
- CEP164 | c.2854G>A p.A952T | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.338); catalogued as rs773981726, COSV104378788; called by muse, mutect2
- CERKL | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 124/246 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.103); catalogued as rs1180928247, COSV59208345; called by muse, mutect2, varscan2
- CETN1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 262/567 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV59121768; called by muse, mutect2, varscan2
- CFAP45 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 29/535 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs766454855, COSV63650277; called by muse, mutect2
- CFAP47 | c.7418G>A p.R2473H | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1388166915; called by muse, mutect2, varscan2
- CLCA4 | c.2362C>T p.R788C | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs553556484, COSV100991174; called by muse, mutect2, varscan2
- CNTN4 | c.2716G>A p.G906R | Missense Mutation (SNP) | VAF 118/265 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.63); catalogued as rs371362562, COSV100639240; called by muse, mutect2, varscan2
- CSNKA2IP | c.1028A>C p.K343T | Missense Mutation (SNP) | VAF 155/337 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1014219433; called by muse, mutect2, varscan2
- CTDP1 | c.2045C>T p.T682M | Missense Mutation (SNP) | VAF 279/562 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867198820; called by muse, mutect2, varscan2
- CWC22 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99844131; called by muse, mutect2
- DHTKD1 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 254/492 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs756540722, COSV53802706, COSV99536414; called by muse, varscan2
- DRD5 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 32/540 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs2227852; called by muse, mutect2
- ELK1 | c.1228A>G p.I410V | Missense Mutation (SNP) | VAF 26/626 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs1473919771; called by muse, mutect2
- EPHB1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 244/501 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs373293977; called by muse, mutect2, varscan2
- F2R | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 275/507 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs777334197, COSV59930250; called by muse, mutect2, varscan2
- GABRA6 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 136/324 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754862222, COSV50877427; called by muse, mutect2, varscan2
- GDF1 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 275/530 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.295); catalogued as rs1438878646; called by muse, mutect2, varscan2
- GPR150 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 318/651 reads (49%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.954); catalogued as rs1442232469, COSV66168046; called by muse, mutect2, varscan2
- GTPBP1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 318/616 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1307294473; called by muse, mutect2, varscan2
- HAPLN1 | c.723G>T p.W241C | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV57148358; called by muse, mutect2
- HRAS | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 370/748 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54240340; called by muse, mutect2, varscan2
- HTRA3 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 186/341 reads (55%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1017083985; called by muse, mutect2, varscan2
- INSL6 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767494322, COSV67562518; called by muse, mutect2, varscan2
- KIF26B | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 19/471 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159934380, COSV100832686; called by muse, mutect2
- KMT2B | c.7715C>T p.T2572M | Missense Mutation (SNP) | VAF 181/365 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs867499379, COSV53074231; called by muse, mutect2, varscan2
- LLCFC1 | c.332C>T p.T111M (on ENST00000458732; = p.T80M on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 342/684 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs369000744, COSV100787015; called by muse, mutect2, varscan2
- LRP1B | c.2924G>T p.C975F | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67187329; called by muse, mutect2, varscan2
- MARCHF11 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 31/566 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs1184046140; called by muse, mutect2
- MEGF11 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 89/391 reads (23%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.835); catalogued as rs761041127, COSV56549962; called by muse, mutect2, varscan2
- MTNR1B | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 337/634 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1345298351, COSV57066059; called by muse, mutect2, varscan2
- NCAM1 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 149/296 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs782485722; called by muse, mutect2, varscan2
- NRXN3 | c.881G>A p.R294H (on ENST00000557594 / NM_001272020.2; = p.R926H on NM_004796.6) | Missense Mutation (SNP) | VAF 185/357 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs144373051; called by muse, mutect2, varscan2
- NT5C2 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58414717, COSV58414729; called by muse, mutect2, varscan2
- NWD2 | c.3310G>A p.V1104I | Missense Mutation (SNP) | VAF 249/495 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs775787015, COSV58754013; called by muse, mutect2, varscan2
- OR2M7 | c.796C>A p.H266N | Missense Mutation (SNP) | VAF 122/232 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV58740004; called by muse, mutect2, varscan2
- OR3A2 | c.671T>C p.I224T | Missense Mutation (SNP) | VAF 33/593 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs771172270; called by muse, mutect2
- PCDH15 | c.4707G>T p.K1569N | Missense Mutation (SNP) | VAF 182/384 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV57258622; called by muse, mutect2, varscan2
- PCDHB9 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 175/441 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); catalogued as rs782422350; called by muse, mutect2, varscan2
- PCDHGB2 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 157/411 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs757587046, COSV53894173; called by muse, mutect2, varscan2
- PCDHGB4 | c.1906G>A p.V636I | Missense Mutation (SNP) | VAF 219/592 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs1328126483, COSV53949039; called by muse, mutect2, varscan2
- PIK3C3 | c.772C>G p.P258A | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV56280167; called by muse, mutect2
- PRMT6 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 116/389 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.052); catalogued as rs539124873, COSV63656223; called by muse, mutect2, varscan2
- RHOXF2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 362/1081 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as rs782250177; called by muse, mutect2, varscan2
- SLC25A1 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 229/425 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); catalogued as rs781963874, COSV53206387; called by muse, mutect2, varscan2
- SOX17 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 404/1281 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as COSV52024544, COSV52025261; called by muse, mutect2, varscan2
- SPATA31A7 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 180/547 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.134); catalogued as rs200244273; called by muse, mutect2, varscan2
- SYNPR | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 72/257 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs779260176, COSV55722268, COSV99888444; called by muse, varscan2
- TANC2 | c.4684G>A p.V1562M | Missense Mutation (SNP) | VAF 232/441 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.495); catalogued as rs368956259, COSV67331062; called by muse, mutect2, varscan2
- TCHHL1 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 197/361 reads (55%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs1342896445; called by muse, mutect2, varscan2
- THOC2 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.28); catalogued as rs761579225; called by muse, mutect2, varscan2
- TMEM259 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 327/691 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs201156482, COSV52261519; called by muse, mutect2
- TNIP1 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs548565909, COSV100161002, COSV100161705; called by muse, mutect2
- TTN | c.9083G>T p.R3028M (on ENST00000591111; = p.R2982M on NM_003319.4) | Missense Mutation (SNP) | VAF 214/475 reads (45%) | PolyPhen probably damaging (0.998); catalogued as COSV60353046; called by muse, mutect2, varscan2
- TUSC3 | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 174/533 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65879134, COSV65887519; called by muse, mutect2, varscan2
- TXNDC12 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 112/276 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217242438; called by muse, mutect2, varscan2
- ULK2 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 190/365 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs372735795; called by muse, mutect2, varscan2
- XKR5 | c.1216C>A p.L406M | Missense Mutation (SNP) | VAF 107/711 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554710625; called by muse, mutect2, varscan2
- XRRA1 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 127/250 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs769038963; called by muse, mutect2, varscan2
- ZFP92 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 464/903 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1556975120, COSV58598291; called by muse, mutect2, varscan2
- ZNF804B | c.2537G>T p.C846F | Missense Mutation (SNP) | VAF 109/292 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.38); catalogued as COSV60814748; called by muse, mutect2, varscan2
- AP1B1 | c.507C>G p.I169M | Missense Mutation (SNP) | VAF 25/325 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2
- APOB | c.5986T>A p.L1996M | Missense Mutation (SNP) | VAF 23/368 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.73); called by muse, mutect2
- ARHGAP6 | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 320/674 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CARMIL3 | c.2155dup p.R719Pfs*19 | Frame Shift Ins (INS) | VAF 164/403 reads (41%) | called by mutect2, pindel, varscan2
- CELSR1 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 228/487 reads (47%) | called by muse, mutect2, varscan2
- CERKL | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 252/492 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- CH25H | c.421G>C p.V141L | Missense Mutation (SNP) | VAF 232/478 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COPS5 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 243/366 reads (66%) | SIFT tolerated (0.28); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DHCR24 | c.344_345del p.M115Nfs*43 | Frame Shift Del (DEL) | VAF 128/352 reads (36%) | called by mutect2, pindel, varscan2
- EEF2K | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 14/403 reads (3%) | called by muse, mutect2
- EFR3A | c.368T>G p.F123C | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERBB2 | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 296/639 reads (46%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- ETNPPL | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 225/437 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EYS | c.4366A>G p.S1456G | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- EYS | c.2966A>C p.N989T | Missense Mutation (SNP) | VAF 100/202 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GRXCR1 | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 113/213 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- GTF2IRD2B | c.2567C>T p.T856M | Missense Mutation (SNP) | VAF 131/501 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HCN1 | c.719A>C p.E240A | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- HSPA5 | c.217dup p.E73Gfs*22 | Frame Shift Ins (INS) | VAF 231/573 reads (40%) | called by mutect2, pindel, varscan2
- IFT172 | c.2644T>C p.C882R | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2
- ITGAM | c.154dup p.Q52Pfs*64 | Frame Shift Ins (INS) | VAF 143/350 reads (41%) | called by mutect2, pindel, varscan2
- ITPR1 | c.1483C>A p.L495I (on ENST00000354582; = p.L480I on NM_002222.7) | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIAA0319L | c.2996G>A p.S999N | Missense Mutation (SNP) | VAF 130/334 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, varscan2
- LGI3 | c.1624A>T p.I542F | Missense Mutation (SNP) | VAF 84/542 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LINC02218 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 171/370 reads (46%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MAP3K15 | c.836T>G p.V279G | Missense Mutation (SNP) | VAF 17/460 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- MAPK3 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 239/506 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MBD3L5 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 13/400 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.382); called by muse, mutect2
- NKAIN2 | c.362C>A p.T121K | Missense Mutation (SNP) | VAF 223/484 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- NOVA2 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 102/190 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- NOX4 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRAP | c.3223C>A p.Q1075K (on ENST00000359988 / NM_001322945.2; = p.Q1040K on NM_006175.4) | Missense Mutation (SNP) | VAF 137/317 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NUP210 | c.4237G>A p.G1413R | Missense Mutation (SNP) | VAF 33/535 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2T11 | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 117/469 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR8H1 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 78/148 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PCDHGA2 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 109/393 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- PPP1R16A | c.1021A>T p.S341C | Missense Mutation (SNP) | VAF 299/904 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- PPP4R3C | c.554T>G p.L185R | Missense Mutation (SNP) | VAF 97/192 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PRRT4 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 12/363 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.011); called by muse, mutect2
- RBM34 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RCVRN | c.105C>A p.F35L | Missense Mutation (SNP) | VAF 127/516 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RHOBTB3 | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RPS6KA1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 159/348 reads (46%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RXFP1 | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 120/247 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SETD2 | c.7429G>A p.E2477K | Missense Mutation (SNP) | VAF 119/264 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- SLC13A3 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 116/340 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- SLC35A5 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 13/372 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC4A10 | c.581T>C p.M194T | Missense Mutation (SNP) | VAF 81/242 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SOX1 | c.1120C>A p.H374N | Missense Mutation (SNP) | VAF 250/545 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- STRAP | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 87/162 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, varscan2
- TAF11L13 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- TENM1 | c.1545G>T p.K515N | Missense Mutation (SNP) | VAF 117/247 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TIPRL | c.800A>G p.K267R | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMCO4 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 192/408 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNRC18 | c.2261_2262insGG p.S754Rfs*21 | Frame Shift Ins (INS) | VAF 196/372 reads (53%) | called by mutect2, varscan2
- TPRG1 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TTN | c.42119C>A p.P14040H (on ENST00000591111; = p.P6616H on NM_003319.4) | Missense Mutation (SNP) | VAF 96/394 reads (24%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13B | c.8853G>T p.K2951N | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.432G>A p.S144= | Silent (SNP) | VAF 277/544 reads (51%) | catalogued as rs139118990; called by muse, mutect2, varscan2
- ADAMTS19 | c.2461A>C p.R821= | Silent (SNP) | VAF 34/330 reads (10%) | catalogued as COSV99177320; called by muse, mutect2
- ADAMTS8 | c.387C>T p.D129= | Silent (SNP) | VAF 32/936 reads (3%) | called by muse, mutect2
- ANKRD24 | c.2931C>T p.N977= | Silent (SNP) | VAF 349/710 reads (49%) | catalogued as rs1019103263; called by muse, mutect2, varscan2
- BCL11A | c.1974G>A p.S658= (on ENST00000335712 / NM_001365609.1; = p.S692= on NM_018014.4) | Silent (SNP) | VAF 250/593 reads (42%) | catalogued as rs146556401; called by muse, mutect2, varscan2
- C4orf54 | c.4998C>T p.A1666= | Silent (SNP) | VAF 187/393 reads (48%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.2133C>T p.T711= | Silent (SNP) | VAF 227/472 reads (48%) | catalogued as rs186741880, COSV100409995; called by muse, mutect2, varscan2
- CD163L1 | c.2361G>A p.L787= | Silent (SNP) | VAF 112/224 reads (50%) | called by muse, mutect2, varscan2
- CHD7 | c.7086C>T p.S2362= | Silent (SNP) | VAF 237/688 reads (34%) | catalogued as rs757280832; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CPQ | c.468C>T p.F156= | Silent (SNP) | VAF 176/541 reads (33%) | catalogued as rs1237209399, COSV55162497; called by muse, mutect2, varscan2
- DAPK1 | c.1905C>T p.S635= | Silent (SNP) | VAF 25/445 reads (6%) | catalogued as rs1230233700; called by muse, mutect2
- DCAF4L2 | c.483G>T p.A161= | Silent (SNP) | VAF 245/745 reads (33%) | catalogued as COSV60480151; called by muse, mutect2, varscan2
- DNAH5 | c.8716C>T p.L2906= | Silent (SNP) | VAF 133/297 reads (45%) | catalogued as COSV54210372; called by muse, mutect2, varscan2
- EPN2 | c.1140A>G p.P380= | Silent (SNP) | VAF 225/429 reads (52%) | catalogued as rs768002641; called by muse, mutect2, varscan2
- FCSK | c.2779C>T p.L927= | Silent (SNP) | VAF 22/571 reads (4%) | called by muse, mutect2
- FOXD4L4 | c.240G>A p.P80= | Silent (SNP) | VAF 96/1372 reads (7%) | called by muse, mutect2
- GPR15 | c.963G>A p.L321= | Silent (SNP) | VAF 195/402 reads (49%) | called by muse, mutect2, varscan2
- GSTM4 | c.222C>T p.N74= | Silent (SNP) | VAF 300/598 reads (50%) | catalogued as rs375225696; called by muse, mutect2, varscan2
- HERC2 | c.13449C>T p.S4483= | Silent (SNP) | VAF 228/496 reads (46%) | catalogued as rs764614115; called by muse, mutect2, varscan2
- HOXB8 | c.291C>T p.F97= | Silent (SNP) | VAF 395/780 reads (51%) | called by muse, varscan2
- IGF1R | c.159G>A p.T53= | Silent (SNP) | VAF 36/766 reads (5%) | catalogued as rs375188453; called by muse, mutect2
- IGHV2-26 | c.165G>A p.V55= | Silent (SNP) | VAF 188/1283 reads (15%) | catalogued as rs1237847762; called by muse, mutect2, varscan2
- MAP3K5 | c.3135G>A p.R1045= | Silent (SNP) | VAF 190/374 reads (51%) | called by muse, mutect2, varscan2
- MC3R | c.684C>T p.D228= | Silent (SNP) | VAF 311/640 reads (49%) | catalogued as COSV54765274; called by muse, mutect2, varscan2
- MUC12 | c.9387A>T p.T3129= (on ENST00000379442; = p.T2986= on NM_001164462.1) | Silent (SNP) | VAF 63/1085 reads (6%) | catalogued as COSV65183707; called by muse, mutect2, varscan2
- MYH7 | c.4641C>T p.A1547= | Silent (SNP) | VAF 96/196 reads (49%) | catalogued as rs376854724; called by muse, varscan2
- NKX1-1 | c.1083C>T p.S361= | Silent (SNP) | VAF 260/478 reads (54%) | called by muse, mutect2, varscan2
- NSG1 | c.222G>A p.T74= | Silent (SNP) | VAF 195/383 reads (51%) | catalogued as rs779838685; called by muse, mutect2, varscan2
- OR14A16 | c.312T>G p.S104= | Silent (SNP) | VAF 104/368 reads (28%) | catalogued as COSV62926276; called by muse, mutect2, varscan2
- PDE3A | c.99G>A p.A33= | Silent (SNP) | VAF 289/642 reads (45%) | called by muse, mutect2, varscan2
- PGR | c.873C>T p.P291= | Silent (SNP) | VAF 384/820 reads (47%) | catalogued as COSV54795552; called by muse, mutect2, varscan2
- PHLDA2 | c.225C>A p.T75= | Silent (SNP) | VAF 42/978 reads (4%) | called by muse, mutect2
- PIK3CG | c.1026C>T p.H342= | Silent (SNP) | VAF 244/506 reads (48%) | catalogued as rs539823993, COSV63253458; called by muse, mutect2, varscan2
- PRDM8 | c.1668C>T p.N556= | Silent (SNP) | VAF 167/658 reads (25%) | called by muse, mutect2, varscan2
- RYR3 | c.11673C>A p.G3891= (on ENST00000389232; = p.G3892= on NM_001036.6) | Silent (SNP) | VAF 64/190 reads (34%) | called by muse, mutect2, varscan2
- SALL2 | c.1554A>G p.E518= | Silent (SNP) | VAF 251/498 reads (50%) | called by muse, mutect2, varscan2
- SLC35D3 | c.579C>T p.I193= | Silent (SNP) | VAF 300/662 reads (45%) | catalogued as rs201285388; called by muse, mutect2, varscan2
- SLC4A1 | c.489C>T p.H163= | Silent (SNP) | VAF 136/330 reads (41%) | catalogued as rs149933181; called by muse, mutect2, varscan2
- SOX17 | c.567C>T p.P189= | Silent (SNP) | VAF 56/1606 reads (3%) | catalogued as rs780594698; called by muse, mutect2
- TIAM1 | c.4521C>T p.D1507= | Silent (SNP) | VAF 227/490 reads (46%) | catalogued as rs1228855775; called by muse, mutect2, varscan2
- TMEM271 | c.141C>T p.A47= | Silent (SNP) | VAF 328/715 reads (46%) | called by muse, mutect2, varscan2
- TRIM64B | c.1215A>C p.R405= | Silent (SNP) | VAF 93/567 reads (16%) | catalogued as rs202169525; called by muse, mutect2, varscan2
- ZFPM2 | c.2505G>A p.K835= | Silent (SNP) | VAF 225/717 reads (31%) | catalogued as COSV65874820; called by muse, mutect2, varscan2
- GABARAPL1 | c.288+119C>T | Intron (SNP) | VAF 183/359 reads (51%) | catalogued as rs1259130198; called by muse, mutect2, varscan2
- LINC00662 | n.687C>T | RNA (SNP) | VAF 137/324 reads (42%) | catalogued as rs768383838; called by muse, mutect2, varscan2
- MYL3 | chr3:46833947 G>A | 3'Flank (SNP) | VAF 313/669 reads (47%) | catalogued as rs868399479; called by muse, mutect2, varscan2
- TBXA2R | c.*24G>A | 3'UTR (SNP) | VAF 298/695 reads (43%) | catalogued as rs200736764; called by muse, mutect2, varscan2
